Somatic mutation profile of tumor specimen TCGA-G3-AAUZ-01A (aliquot TCGA-G3-AAUZ-01A-11D-A382-10) from TCGA case TCGA-G3-AAUZ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 48.6 years (17,760 days).
Specimen TCGA-G3-AAUZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f64ccbb1-1549-46ac-b2ac-7d2257fd54e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-AAUZ-10A (Blood Derived Normal), aliquot TCGA-G3-AAUZ-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67f5a7bf-bda2-43f4-9edc-f65091be7487

The open-access MAF lists 83 somatic variants for this specimen: 67 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 14, Nonsense Mutation 3, In Frame Del 3, Frame Shift Del 2, Splice Site 2, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RMND1 | c.830+1G>A p.X277_splice | Splice Site (SNP) | VAF 22/83 reads (27%) | catalogued as rs773470671, COSV100323477; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS7 | c.1742G>T p.R581L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767569244, COSV101182990; called by muse, mutect2, varscan2
- ANLN | c.1085C>A p.S362Y | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV99731648; called by muse, mutect2, varscan2
- ASH1L | c.8390T>G p.I2797S (on ENST00000368346 / NM_001366177.2; = p.I2792S on NM_018489.3) | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100853043; called by muse, mutect2, varscan2
- ATP2A2 | c.2014G>T p.A672S | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV100428309; called by muse, mutect2, varscan2
- BCL7B | c.583G>T p.V195L | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV99790225; called by muse, mutect2, varscan2
- BNC2 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 67/152 reads (44%) | catalogued as COSV101031722; called by muse, mutect2, varscan2
- CALD1 | c.2087A>C p.K696T (on ENST00000361675 / NM_033138.4; = p.K441T on NM_004342.7) | Missense Mutation (SNP) | VAF 79/196 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100723922; called by muse, mutect2, varscan2
- CHD6 | c.6854G>C p.R2285T | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100950468; called by muse, mutect2, varscan2
- CIT | c.616A>G p.I206V | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99948030; called by muse, mutect2, varscan2
- COL5A1 | c.4121C>T p.T1374M | Missense Mutation (SNP) | VAF 71/199 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs151115748; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL9A2 | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.106); catalogued as rs148912050; called by muse, mutect2, varscan2
- CPNE8 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 117/298 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs754785078, COSV58845451; called by muse, mutect2, varscan2
- CRACD | c.31A>T p.I11F | Missense Mutation (SNP) | VAF 87/139 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99948332; called by muse, mutect2, varscan2
- CYP8B1 | c.1293G>T p.M431I | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100295939; called by muse, mutect2, varscan2
- DISC1 | c.2197C>A p.P733T | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs773300398, COSV100790088; called by muse, mutect2, varscan2
- DNAH17 | c.7552G>C p.V2518L | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV101101087; called by muse, mutect2, varscan2
- FAF2 | c.692C>A p.P231Q | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99990149; called by muse, mutect2, varscan2
- FAM91A1 | c.218A>G p.D73G | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as COSV100593406; called by muse, mutect2
- FAP | c.2194C>A p.Q732K | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV99501511; called by muse, mutect2, varscan2
- FAT4 | c.151G>T p.V51L | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.949); catalogued as COSV101271700; called by muse, mutect2, varscan2
- FNTA | c.836A>C p.Y279S | Missense Mutation (SNP) | VAF 158/284 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100172342; called by muse, mutect2, varscan2
- FOXC2 | c.589A>T p.T197S | Missense Mutation (SNP) | VAF 244/405 reads (60%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100234056; called by muse, mutect2, varscan2
- FOXN3 | c.437A>G p.E146G | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV99725531; called by muse, mutect2, varscan2
- HNRNPM | c.1302del p.I434Mfs*94 | Frame Shift Del (DEL) | VAF 37/115 reads (32%) | catalogued as COSV55312315; called by mutect2, pindel, varscan2
- HOOK1 | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 228/668 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.309); catalogued as COSV100968941; called by muse, mutect2, varscan2
- ITPR3 | c.2323G>T p.A775S | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100966789, COSV65407322; called by muse, mutect2
- LFNG | c.475C>T p.H159Y (on ENST00000222725 / NM_001040167.2; = p.H30Y on NM_002304.2) | Missense Mutation (SNP) | VAF 93/263 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.348); catalogued as COSV56070631; called by muse, mutect2, varscan2
- MCC | c.135G>C p.Q45H | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV101376733; called by muse, mutect2, varscan2
- MICAL1 | c.1067A>T p.H356L | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100668362; called by muse, mutect2, varscan2
- MTIF2 | c.1435G>T p.E479* | Nonsense Mutation (SNP) | VAF 55/133 reads (41%) | catalogued as COSV99708911, COSV99709083; called by muse, mutect2, varscan2
- MYO1H | c.458A>G p.D153G | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV100182952; called by muse, mutect2, varscan2
- MYOM2 | c.2983G>T p.V995F | Missense Mutation (SNP) | VAF 51/75 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV100036360; called by muse, mutect2, varscan2
- NCOR1 | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 45/65 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51998752; called by muse, mutect2, varscan2
- NLK | c.1014A>T p.R338S | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100817295; called by muse, mutect2
- NR1I2 | c.415G>T p.G139* | Nonsense Mutation (SNP) | VAF 8/126 reads (6%) | catalogued as rs1206018744, COSV100561393; called by muse, mutect2
- NRDC | c.3613T>G p.F1205V | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100542798; called by muse, mutect2, varscan2
- PDGFD | c.1041G>T p.M347I | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.968); catalogued as COSV100157414; called by muse, mutect2, varscan2
- POLR3C | c.437A>G p.N146S | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100492723; called by muse, mutect2, varscan2
- PRAMEF12 | c.187T>C p.C63R | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100742915; called by muse, mutect2, varscan2
- PWWP3A | c.632A>G p.N211S (on ENST00000627377; = p.N210S on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as COSV100261640; called by muse, mutect2, varscan2
- RPF1 | c.416A>T p.Q139L | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV101039654; called by muse, mutect2, varscan2
- RYR1 | c.11372C>A p.A3791D | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.036); catalogued as COSV100614083; called by muse, mutect2, varscan2
- SACS | c.10844A>C p.N3615T | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.084); catalogued as COSV101207119, COSV66547961; called by muse, mutect2, varscan2
- SAMHD1 | c.1131A>C p.K377N | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99483720; called by muse, mutect2, varscan2
- SERINC1 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs778207588, COSV60101613; called by muse, mutect2, varscan2
- SMARCA2 | c.1694A>C p.K565T | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.118); catalogued as COSV100570111; called by muse, mutect2, varscan2
- SMG1 | c.9134G>T p.G3045V | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV101244919; called by muse, mutect2, varscan2
- SPECC1 | c.1052A>G p.K351R | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV99821007; called by muse, mutect2
- SPHKAP | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100763559; called by muse, mutect2, varscan2
- SYNE1 | c.21959C>T p.S7320L (on ENST00000367255 / NM_182961.4; = p.S7249L on NM_033071.3) | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV99549856; called by muse, mutect2, varscan2
- THBS1 | c.604G>T p.G202W | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99527427; called by muse, mutect2, varscan2
- THRAP3 | c.1619A>G p.K540R | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.119); catalogued as rs1241368025, COSV100663127; called by muse, mutect2, varscan2
- TLL1 | c.1766G>A p.R589Q | Missense Mutation (SNP) | VAF 91/137 reads (66%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.724); catalogued as rs750536542, COSV50333926; called by muse, mutect2, varscan2
- TMEM270 | c.763A>G p.T255A | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100260272; called by muse, mutect2, varscan2
- TTC3 | c.1580A>G p.Q527R | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as rs1424044877, COSV100694893, COSV61292418; called by muse, mutect2, varscan2
- UMODL1 | c.1703G>C p.G568A | Missense Mutation (SNP) | VAF 139/283 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.084); catalogued as COSV100210436; called by muse, mutect2, varscan2
- USP48 | c.2374G>A p.D792N | Missense Mutation (SNP) | VAF 102/456 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.534); catalogued as COSV100379334, COSV57608261; called by muse, varscan2
- WNT3A | c.652T>A p.W218R | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99468603; called by muse, mutect2, varscan2
- ZBTB24 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.829); catalogued as COSV100018253; called by muse, mutect2, varscan2
- ZRANB1 | c.949C>T p.H317Y | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV100669032; called by muse, mutect2, varscan2
- CNPY3 | c.496-2_496-1del p.X166_splice | Splice Site (DEL) | VAF 35/177 reads (20%) | called by mutect2, pindel, varscan2
- MYO5C | c.587_604del p.A196_T201del | In Frame Del (DEL) | VAF 15/64 reads (23%) | called by mutect2, pindel, varscan2
- PALM2AKAP2 | c.1894_1896del p.P632del (on ENST00000259318 / NM_001136562.3; = p.P863del on NM_007203.5) | In Frame Del (DEL) | VAF 12/59 reads (20%) | called by mutect2, pindel, varscan2
- RBP3 | c.2294T>C p.V765A | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- SLC2A2 | c.172_174del p.N58del | In Frame Del (DEL) | VAF 36/146 reads (25%) | called by pindel, varscan2
- UBE2D3 | c.394_395del p.D132* | Frame Shift Del (DEL) | VAF 210/532 reads (39%) | called by pindel, varscan2
- AADACL3 | c.1134A>G p.G378= | Silent (SNP) | VAF 48/111 reads (43%) | catalogued as COSV100206512; called by muse, mutect2, varscan2
- AKR1C1 | c.345T>G p.L115= | Silent (SNP) | VAF 16/166 reads (10%) | catalogued as rs766719242, COSV101080316; called by muse, mutect2
- ATF5 | c.66A>C p.G22= | Silent (SNP) | VAF 51/143 reads (36%) | catalogued as COSV100351716; called by muse, mutect2, varscan2
- EPHB2 | c.1791C>T p.I597= (on ENST00000400191 / NM_001309193.2; = p.I598= on NM_004442.7) | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs745346872, COSV65860214; called by muse, mutect2, varscan2
- FZD8 | c.333C>T p.C111= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV101020169; called by muse, mutect2, varscan2
- KIAA1549L | c.4047C>A p.A1349= (on ENST00000321505; = p.A1646= on NM_012194.3) | Silent (SNP) | VAF 57/127 reads (45%) | catalogued as COSV100380634, COSV58588946; called by muse, mutect2, varscan2
- MAGI2 | c.3558G>T p.G1186= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as COSV100831878, COSV62660490; called by muse, mutect2, varscan2
- MARK4 | c.1527A>G p.R509= | Silent (SNP) | VAF 39/103 reads (38%) | catalogued as COSV99487749; called by muse, mutect2, varscan2
- ONECUT1 | c.198A>C p.G66= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1204492261, COSV100008965; called by muse, mutect2, varscan2
- SAP18 | c.312G>A p.K104= (on ENST00000607003; = p.K123= on NM_005870.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 68/318 reads (21%) | catalogued as COSV101229413; called by muse, mutect2, varscan2
- SLC2A2 | c.201G>C p.L67= | Silent (SNP) | VAF 35/165 reads (21%) | catalogued as COSV100049004; called by muse, varscan2
- SYNPO2 | c.429T>A p.A143= | Silent (SNP) | VAF 65/258 reads (25%) | catalogued as COSV61108279; called by muse, mutect2, varscan2
- TAF6 | c.1950T>C p.A650= | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as rs923870842, COSV59841431; called by muse, varscan2
- TNFRSF4 | c.285G>C p.R95= | Silent (SNP) | VAF 45/101 reads (45%) | catalogued as COSV55421178, COSV99767253; called by muse, mutect2, varscan2
- FFAR1 | c.*1C>T | 3'UTR (SNP) | VAF 23/42 reads (55%) | catalogued as rs763046473, COSV99876544; called by muse, mutect2, varscan2
- MIR29B2 | n.9A>C | RNA (SNP) | VAF 183/488 reads (38%) | called by muse, mutect2, varscan2
